Somatic mutation profile of tumor specimen TCGA-TM-A7CF-01A (aliquot TCGA-TM-A7CF-01A-11D-A32B-08) from TCGA case TCGA-TM-A7CF, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 41.6 years (15,178 days).
Specimen TCGA-TM-A7CF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7b55270-953c-4e62-9f13-3d535dca8003.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A7CF-10A (Blood Derived Normal), aliquot TCGA-TM-A7CF-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fc833c5-f835-477c-8aa4-2d51f4cee032

The open-access MAF lists 30 somatic variants for this specimen: 28 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 24, Splice Site 2, Silent 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/86 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABHD16B | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99410782; called by muse, mutect2, varscan2
- ADAMTS9 | c.1211-2A>G p.X404_splice | Splice Site (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99899822; called by muse, mutect2
- ADGRV1 | c.7255C>G p.P2419A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV101316179; called by muse, mutect2, varscan2
- ATP7A | c.4396T>C p.S1466P | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100431219; called by muse, mutect2
- CELSR2 | c.6079T>C p.S2027P | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99604320; called by muse, mutect2, varscan2
- DCDC1 | c.3284G>A p.S1095N (on ENST00000597505 / NM_001367979.1; = p.S202N on NM_020869.3) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as COSV100338503; called by muse, mutect2, varscan2
- FGA | c.1936G>T p.G646C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100120524; called by muse, mutect2, varscan2
- FLNA | c.4962C>A p.H1654Q | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV100774899; called by muse, mutect2, varscan2
- GMPPA | c.1224G>C p.K408N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100354738; called by muse, mutect2, varscan2
- IQSEC1 | c.2482A>C p.T828P | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV99832095; called by muse, mutect2
- LPCAT3 | c.1124G>A p.G375D | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781157; called by muse, mutect2
- NOL4 | c.265-1G>A p.X89_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | catalogued as COSV99304862, COSV99307422; called by muse, mutect2
- NRROS | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs139647726; called by muse, mutect2, varscan2
- OR52E4 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs757270158, COSV57623791, COSV57625916; called by muse, varscan2
- OTOS | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs750554667, COSV56228628; called by muse, mutect2, varscan2
- PPP1R10 | c.2336G>A p.S779N | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV64738555; called by muse, mutect2
- RNF17 | c.2128A>G p.I710V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs368259164; called by muse, mutect2, varscan2
- RNGTT | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs759501463, COSV99666350; called by muse, mutect2, varscan2
- SMAD9 | c.881G>A p.R294Q (on ENST00000379826 / NM_001127217.3; = p.R257Q on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs1382800676, COSV63205705; called by muse, mutect2, varscan2
- THRAP3 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100663459; called by muse, mutect2, varscan2
- TMEM14A | c.246G>C p.L82F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV99276000; called by muse, varscan2
- UGT2B7 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as rs776991562, COSV59442567; ClinVar: drug response; called by muse, mutect2
- ZBTB14 | c.976A>C p.I326L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.099); catalogued as COSV100813477; called by muse, mutect2, varscan2
- ZSWIM8 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1229642366, COSV101290028; called by muse, mutect2, varscan2
- FASTKD3 | c.693_694del p.G232Lfs*14 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by mutect2, pindel, varscan2
- MOSPD2 | c.927_959del p.D310_L320del | In Frame Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel
- HIRA | c.702G>T p.G234= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99600626; called by muse, mutect2, varscan2
- SV2B | c.771C>T p.I257= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
